Surgical pathology report (de-identified scan), TCGA case TCGA-AA-3976, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Indivumed, specimen TCGA-AA-3976-01A (Primary Tumor).

Diagnosis:

Resected rectosigmoid sample including a moderately differentiated adenocarcinoma of the colorectal type, located 3.5 cm aborally of the aboral resection margin, measuring max 2.3 cm in diameter, with infiltration of the tunica muscularis propria and two regional lymph node metastases.

Stage of tumor: pT2, pN1 (2/16) MX; G2, V0, R0

Source: NCI Genomic Data Commons file 0c364ef0-a6a0-4778-81ac-a0e18ebce96f (TCGA-AA-3976.7AB12244-C3C7-4297-8375-7324C8FAE99C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).